FM case AD4377 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/88e2cdd0-913b-403f-ab30-8ffcc9fc19f1

Female, 68.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
